Gene-level copy-number profile of tumor specimen CDDP-ABIX-TTP2-A from CDDP_EAGLE case CDDP-ABIX, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 60 years.
Specimen CDDP-ABIX-TTP2-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6a8404e1-e8ff-4115-a9a0-1c8ee4ae1ec6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ABIX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate.
https://portal.gdc.cancer.gov/files/d0982f72-c651-41f7-bb1a-7ad262a3a463

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 22; copy number 2: 161; copy number 3: 7,806; copy number 4: 16,899; copy number 5: 13,900; copy number 6: 6,984; copy number 7: 6,343; copy number 8: 1,425; copy number 9: 2,519; copy number 10: 926; copy number 11: 1,164; copy number 12: 169; copy number 13: 55; copy number 16: 1; copy number 30: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:44,944,015–44,944,961, 1 gene: PRDX4P1.
- chr5:125,966,777–125,968,085, 1 gene: RPSAP37.
- chr6:81,724,722–81,736,353, 1 gene (within-gene range 0–2): AL078599.2.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr8:105,737,280–105,737,765, 1 gene (within-gene range 0–5): RPL12P24.
- chr9:80,563,571–80,565,962, 2 genes: MTCO1P51, MTND2P9.
- chr10:38,783,004–38,783,108, 1 gene: AL590623.1.
- chr18:29,048,620–29,048,719, 1 gene: RNU6-408P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,835 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,063,737–155,563,162, 34 genes, copy number 9 (within-gene range 5–9): EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4.
- chr6:24,126,186–45,377,953, 929 genes, copy number 11–12 (within-gene range 7–12) (broad region; genes not listed).
- chr6:48,701,491–52,669,155, 53 genes, copy number 11–13: FO393412.1, AL022099.1, AL589994.1, AL589994.2, FO393413.1, RNU7-65P, EEF1A1P42, MMUT, CENPQ, GLYATL3, C6orf141, CYP2AC1P, RHAG, CRISP2, AL121974.1, AL121950.1, CRISP3, PGK2, AL359458.1, CRISP1, DEFB133, DEFB114, DEFB113, DEFB110, DEFB112, AL138826.1, AL360175.1, AL135908.1, TFAP2D, TFAP2B, RPS17P5, AL049693.1, FTH1P5, AL158050.2, AL158050.1, AL365219.1, AL445529.1, AL355997.1, PKHD1, RN7SL580P, MIR206, LINCMD1, MIR133B, IL17A, IL17F, SLC25A20P1, MCM3, PAQR8, EFHC1, TRAM2, TRAM2-AS1, AL109918.2, AL109918.1.
- chr6:53,929,982–55,875,590, 21 genes, copy number 13: MLIP, AL033384.1, MLIP-AS1, MLIP-IT1, ERHP2, AL359380.1, TINAG, TINAG-AS1, CLNS1AP1, RPL10P10, RPSAP44, KRASP1, RNU6-1023P, AL512363.1, FAM83B, AL049555.1, HCRTR2, GFRAL, HMGCLL1, AL590290.1, BMP5.
- chr7:37,032–57,837,046, 1,034 genes, copy number 9–10 (broad region; genes not listed).
- chr7:63,011,463–69,046,803, 205 genes, copy number 9 (broad region; genes not listed).
- chr7:69,186,821–93,574,730, 352 genes, copy number 9–10 (within-gene range 1–10) (broad region; genes not listed).
- chr7:93,669,826–159,233,377, 1,336 genes, copy number 9 (broad region; genes not listed).
- chr12:12,310–34,249,958, 834 genes, copy number 10–11 (broad region; genes not listed).
- chr12:38,150,050–39,908,300, 23 genes, copy number 11 (within-gene range 4–11): AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40.
- chr12:39,819,750–39,819,883, 1 gene, copy number 11 (within-gene range 4–11): AC121336.1.
- chr12:43,155,315–43,806,328, 10 genes, copy number 12: LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1.
- chr14:18,333,726–18,419,273, 3 genes, copy number 13–30: CR383658.1, CR383658.2, BNIP3P6.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
